TCGA case TCGA-HM-A3JJ — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: Christiana Healthcare. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f150d999-cdec-427e-b8b2-00731c648989

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 40 years; Vital status: Dead; Days to death: 659 days (1.8 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 40.3 years (14,736 days); Year of diagnosis: 2010; Method of diagnosis: Biopsy; AJCC pathologic T: T1b1; AJCC pathologic N: N1; AJCC pathologic M: MX; FIGO stage: Stage IB1; FIGO staging edition year: 2009; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 4; Lymph nodes tested: 41; Lymphatic invasion present: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 110 days; Days to treatment end: 138 days; Number of cycles: 5; Treatment dose: 350 mg; Prescribed dose: 70; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 110 days; Days to treatment end: 150 days; Treatment dose: 5,040 cGy; Course number: 1; Number of fractions: 28; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, Cyberknife; Treatment intent type: Palliative; Days to treatment start: 530 days (1.5 years); Days to treatment end: 532 days (1.5 years); Treatment dose: 2,250 cGy; Course number: 2; Number of fractions: 3; Treatment anatomic sites: Locoregional Site.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS). Age at diagnosis: 41.4 years (15,121 days); Days to diagnosis: 385 days (1.1 years); Prior treatment: Yes.

Follow-up (9 entries)
- Day 13 (preoperative): Days to imaging: 13 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 13 (preoperative): Days to imaging: 13 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Pelvic Lymph Node Involvement.
- Day 13 (preoperative): Days to imaging: 13 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 13 (preoperative): Days to imaging: 13 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 13 (preoperative): Days to imaging: 13 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 13 (preoperative): Days to imaging: 13 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 26 (preoperative): ECOG performance status: 0.
- Day 385 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 385 days (1.1 years); Evidence of progression type: Biopsy with Histologic Confirmation.
- Days to follow up: 659 days (1.8 years); Disease response: With Tumor.

Molecular and laboratory tests
- Human Papillomavirus: Positive [Hpv strain: HPV18].
- Human Papillomavirus: Positive [Hpv strain: HPV52].
- Human Papillomavirus: Positive [Hpv strain: HPV68].
- Human Papillomavirus: Positive [Hpv strain: HPV35].
- Human Papillomavirus: Positive [Hpv strain: HPV51].
- Human Papillomavirus: Positive [Hpv strain: HPV56].
- Human Papillomavirus: Positive [Hpv strain: HPV58].
- Human Papillomavirus: Positive [Hpv strain: HPV39].
- Human Papillomavirus: Positive [Hpv strain: HPV59].
- Human Papillomavirus: Positive [Hpv strain: HPV31].
- Human Papillomavirus: Positive [Hpv strain: HPV33].
- Human Papillomavirus: Positive [Hpv strain: HPV45].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 173 cm; BMI: 24.1.
- Timepoint category: Prior to Diagnosis; Comorbidities: Human Papillomavirus Infection; Risk factors: Human Papillomavirus Infection.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 4+; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-HM-A3JJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 680 mg.
  Slide TCGA-HM-A3JJ-01A-02-TS2: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 60; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 10; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 1.
- Sample TCGA-HM-A3JJ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-HM-A3JJ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-HM-A3JJ-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 950 mg.
  Slide TCGA-HM-A3JJ-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 5; Pregnancies count induced abortion: 1; Pregnant at diagnosis: No; Total pregnancy count: 6; Tumor response: Complete response; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Cone Biopsy / LEEP; Lymph nodes examined: Yes; Lymphovascular invasion: Present; HPV types other: 18,31,33,35,39,45,51,52,56,58,59,68.
- Diagnostic ct result outcomes: Ct scan preop results: Bladder Absent; Ct scan preop results: Extra-Pelvic Metastatic Disease Absent; Ct scan preop results: Parametrium Absent; Ct scan preop results: Paraaortic Nodes Absent; Ct scan preop results: Pelvic Nodes Absent; Ct scan preop results: Supraclavicular Absent.
- Human papillomavirus types: HPV types positive: Other HPV type(s).
- Follow-up form: Tumor status: With tumor; Cause of death: Cervical Cancer; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Progressive Disease; Radiation adjuvant indicator: Yes; Chemo concurrent dose: 70 mg; Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 5; New tumor event type: Distant Metastasis; New tumor event surgery: Fine needle aspiration biopsy; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: No.
- Follow-up form, Radiation supplemental: Radiation therapy status: Completed as Planned.
- Drug treatment: Regimen number: 1.
- Drug treatment, Route of administrations: Route of administration: IV.
- Radiation treatment 1: Radiation type other: Cyberknife.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 659 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 659 days; disease-free interval: event (new tumor event after initially disease-free), 385 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 385 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-HM-A3JJ-01A-21D-A21P-01): tumor purity 0.42, ploidy 2.61, whole-genome doublings 1.
